Somatic mutation profile of tumor specimen 0DV4IX from CCDI case PBCLCT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Pigmented dermatofibrosarcoma protuberans; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 11.6 years (4,242 days).
Specimen 0DV4IX: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 20c0e0fa-5a65-45dd-90c7-b5b398e27281.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DV4IO (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bfaf7cce-db43-419e-ab44-1b2b70ba9fbe

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- OXSM | c.755G>A p.R252Q | Missense Mutation (SNP) | VAF 460/1249 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); catalogued as rs182478011; called by muse, mutect2
- MYSM1 | c.818C>T p.S273F | Missense Mutation (SNP) | VAF 425/1277 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- PLK2 | c.1004dup p.L335Ffs*12 | Frame Shift Ins (INS) | VAF 278/774 reads (36%) | called by mutect2, varscan2
- GYPA | c.358-97T>A | Intron (SNP) | VAF 71/169 reads (42%) | catalogued as rs562322110, COSV51626065; called by muse, mutect2, varscan2
